Somatic mutation profile of tumor specimen TCGA-E5-A4TZ-01A (aliquot TCGA-E5-A4TZ-01A-11D-A31L-08) from TCGA case TCGA-E5-A4TZ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 64.5 years (23,566 days).
Specimen TCGA-E5-A4TZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ee09409-430b-49b0-9619-67759863122e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E5-A4TZ-10B (Blood Derived Normal), aliquot TCGA-E5-A4TZ-10B-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a38b80ba-cd44-4e19-8815-9f3263d5640d

The open-access MAF lists 516 somatic variants for this specimen: 379 protein-altering or splice-affecting, 126 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 325, Silent 126, Nonsense Mutation 29, Frame Shift Del 10, Splice Site 9, Intron 5, In Frame Del 3, Splice Region 2, RNA 2, Nonstop Mutation 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.3836+1G>A p.X1279_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | catalogued as rs200782888, CS056749, COSV52117332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1216-1G>C p.X406_splice | Splice Site (SNP) | VAF 70/80 reads (88%) | hotspot (GDC flag); catalogued as CS971888, COSV57295479, COSV57298451, COSV57332521; called by muse, mutect2, varscan2
- SCN1A | c.5710C>T p.Q1904* (on ENST00000303395 / NM_001202435.3; = p.Q1893* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/115 reads (18%) | catalogued as rs796053103, CM072022, COSV57689195; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 51/70 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.9686C>T p.S3229L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV71284741; called by muse, mutect2, varscan2
- ABCA3 | c.1612-2A>C p.X538_splice | Splice Site (SNP) | VAF 40/105 reads (38%) | catalogued as CS057374, COSV57050999; called by muse, mutect2, varscan2
- ABCB5 | c.3327G>C p.E1109D (on ENST00000404938 / NM_001163941.2; = p.E664D on NM_178559.6) | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.096); catalogued as COSV51705599, COSV51709393; called by muse, mutect2, varscan2
- ACSM2A | c.352G>C p.E118Q (on ENST00000219054; = p.E39Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV54583181; called by muse, mutect2, varscan2
- ADGRL3 | c.3620G>A p.R1207Q (on ENST00000506720 / NM_001322402.2; = p.R1139Q on NM_015236.6) | Missense Mutation (SNP) | VAF 67/95 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs372464266, COSV72229973; called by muse, mutect2, varscan2
- AGMAT | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs770873087, COSV65435711; called by muse, mutect2, varscan2
- AGMO | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs749599974, COSV61108331; called by muse, mutect2, varscan2
- AGO3 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV55790614, COSV55792026; called by muse, mutect2
- AMBRA1 | c.1565G>T p.G522V (on ENST00000458649 / NM_001367468.1; = p.G432V on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV54050408; called by muse, mutect2, varscan2
- AMER1 | c.2940G>T p.L980F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100366753; called by muse, mutect2, varscan2
- ANK2 | c.2821G>C p.E941Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52151630; called by muse, mutect2, varscan2
- ANKRD26 | c.2930G>A p.R977Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763003415, COSV65774563; called by muse, mutect2, varscan2
- AP2A1 | c.2332C>G p.L778V | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.187); catalogued as COSV58240955, COSV58241025; called by muse, mutect2, varscan2
- ARG1 | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.686); catalogued as COSV51580505, COSV51580721; called by muse, mutect2, varscan2
- ARGFX | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 37/172 reads (22%) | catalogued as COSV57684068; called by muse, mutect2, varscan2
- ARHGAP21 | c.2650G>A p.E884K | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57603662; called by muse, mutect2
- ARHGEF28 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944963285, COSV55250555; called by muse, mutect2, varscan2
- ARID1A | c.5942G>A p.C1981Y | Missense Mutation (SNP) | VAF 81/124 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61373894; called by muse, mutect2, varscan2
- ARID4A | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.31); catalogued as COSV62162611; called by muse, mutect2, varscan2
- ARID4A | c.2401G>C p.D801H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV62162621, COSV62163028, COSV62164588; called by muse, mutect2, varscan2
- ARID4A | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.214); catalogued as COSV62162632; called by muse, mutect2, varscan2
- ARID4A | c.3306G>C p.K1102N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV62162642; called by muse, mutect2, varscan2
- ASPSCR1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs780601115, COSV60727740; called by muse, mutect2, varscan2
- ATP1A2 | c.2129C>G p.A710G | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100767760, COSV63402846; called by muse, mutect2, varscan2
- B3GNT4 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 384/448 reads (86%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.799); catalogued as rs140214004; called by muse, mutect2, varscan2
- BBS10 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV53879714; called by muse, mutect2, varscan2
- BDP1 | c.4831G>C p.D1611H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV62429810; called by muse, mutect2, varscan2
- BHLHE22 | c.827C>G p.S276W | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58861467; called by muse, mutect2, varscan2
- C11orf54 | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV58679604; called by muse, mutect2, varscan2
- C17orf80 | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.574); catalogued as COSV52145426; called by muse, mutect2, varscan2
- C1QTNF12 | c.401C>G p.S134* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100382623; called by muse, mutect2, varscan2
- C1QTNF12 | c.191C>G p.S64* | Nonsense Mutation (SNP) | VAF 26/108 reads (24%) | catalogued as COSV100382626; called by muse, varscan2
- C9orf43 | c.1310C>G p.S437C | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV55912141; called by muse, mutect2, varscan2
- CACNA1E | c.4194G>T p.E1398D | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV62385755; called by muse, mutect2, varscan2
- CAMSAP3 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.054); catalogued as COSV50331755; called by muse, mutect2, varscan2
- CCDC158 | c.1452G>C p.L484F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV66355419, COSV66356757, COSV66357443; called by muse, mutect2, varscan2
- CD101 | c.1900G>C p.E634Q | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV56716863, COSV99869832; called by muse, mutect2, varscan2
- CD93 | c.1568C>G p.S523C | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV55664034; called by muse, mutect2, varscan2
- CD99 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.074); catalogued as rs771793015, COSV66989209; called by muse, mutect2, varscan2
- CDK9 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.078); catalogued as COSV64723539; called by muse, mutect2
- CEP83 | c.1861G>C p.D621H | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51571485; called by muse, mutect2, varscan2
- CFAP54 | c.5957C>T p.S1986L | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.188); catalogued as COSV61571243; called by muse, mutect2, varscan2
- CHAD | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV51972416; called by muse, mutect2
- CHAF1A | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs757142234, COSV56670977; called by muse, mutect2, varscan2
- CHD4 | c.2960G>C p.R987P (on ENST00000357008 / NM_001363606.2; = p.R1000P on NM_001273.5) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100538826, COSV58896698, COSV58901707; called by muse, mutect2, varscan2
- CKMT2 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV54172499; called by muse, mutect2, varscan2
- CLASP1 | c.1739G>C p.R580T | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV55317459; called by muse, mutect2
- CLCNKA | c.201G>C p.M67I | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV58890806; called by muse, mutect2, varscan2
- CLEC4E | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV55225281; called by muse, mutect2, varscan2
- CLIC1 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV65383754; called by muse, mutect2, varscan2
- CLK2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV62876727; called by muse, mutect2, varscan2
- CLN3 | c.1172C>G p.S391C (on ENST00000360019 / NM_001286104.2; = p.S415C on NM_000086.2) | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.907); catalogued as COSV61105142; called by muse, mutect2
- CLN6 | c.906C>G p.F302L | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV51116471; called by muse, mutect2, varscan2
- CNOT6 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56159767, COSV56161849; called by muse, mutect2, varscan2
- CNTNAP1 | c.1157C>G p.S386* | Nonsense Mutation (SNP) | VAF 12/133 reads (9%) | catalogued as COSV99226767; called by muse, mutect2
- CNTRL | c.797G>C p.R266T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99443142; called by muse, mutect2, varscan2
- COA5 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 15/104 reads (14%) | catalogued as COSV100158732; called by muse, mutect2, varscan2
- COL12A1 | c.3407G>C p.G1136A | Missense Mutation (SNP) | VAF 61/287 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV59391821; called by muse, mutect2, varscan2
- COPG1 | c.171G>A p.Q57= | Splice Region (SNP) | VAF 45/118 reads (38%) | catalogued as COSV59112980; called by muse, mutect2, varscan2
- CPD | c.3914C>G p.S1305* | Nonsense Mutation (SNP) | VAF 10/125 reads (8%) | catalogued as COSV99853094; called by muse, mutect2
- CPO | c.810G>C p.L270F | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55939045; called by muse, mutect2, varscan2
- CPS1 | c.3866A>G p.D1289G | Missense Mutation (SNP) | VAF 86/105 reads (82%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV51805007; called by muse, mutect2, varscan2
- CPT1C | c.1782C>A p.F594L | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54918218, COSV99773566; called by muse, mutect2, varscan2
- CRYBG2 | c.4768G>T p.G1590* | Nonsense Mutation (SNP) | VAF 14/103 reads (14%) | catalogued as COSV57484495; called by mutect2, varscan2
- CSK | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV99583772; called by muse, mutect2
- CTBP2 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as rs76079088, COSV58333149; called by muse, mutect2, varscan2
- CTTN | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV57230879; called by muse, mutect2
- CTTNBP2 | c.1622A>G p.N541S | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV50392074; called by muse, mutect2, varscan2
- CUL9 | c.2584G>T p.G862W | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52726609; called by muse, mutect2, varscan2
- CUTC | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452588908, COSV65081607; called by muse, mutect2, varscan2
- CYB5R3 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs536045979, COSV61545139; called by muse, mutect2, varscan2
- DAAM2 | c.2968C>T p.R990C (on ENST00000274867 / NM_001201427.2; = p.R989C on NM_015345.3) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs368619961, COSV51362996; called by muse, mutect2, varscan2
- DCLRE1B | c.1564G>C p.D522H | Missense Mutation (SNP) | VAF 69/133 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65812337; called by muse, mutect2, varscan2
- DDX11 | c.2284G>C p.E762Q (on ENST00000545668 / NM_152438.2; = p.E712Q on NM_004399.3) | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.359); catalogued as COSV52501335; called by muse, mutect2
- DDX17 | c.2050C>G p.R684G | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.28); catalogued as COSV53246938; called by muse, mutect2, varscan2
- DENND2C | c.1667+1G>A p.X556_splice (on ENST00000393274 / NM_001256404.2; = p.X499_splice on NM_198459.4) | Splice Site (SNP) | VAF 13/44 reads (30%) | catalogued as COSV67920431; called by muse, mutect2, varscan2
- DGKH | c.3245C>A p.S1082Y | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV54929195; called by muse, mutect2, varscan2
- DMXL2 | c.8596C>G p.L2866V | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs775720567, COSV51842506; called by muse, mutect2, varscan2
- DNAH17 | c.6859G>C p.E2287Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV67751144, COSV67764096; called by muse, mutect2, varscan2
- DNAH5 | c.9350G>T p.W3117L | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54211920; called by muse, mutect2, varscan2
- DNHD1 | c.1387C>T p.R463* | Nonsense Mutation (SNP) | VAF 56/123 reads (46%) | catalogued as rs767629627, COSV54436105; called by muse, mutect2, varscan2
- DOT1L | c.3314C>T p.P1105L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV67108572; called by muse, mutect2, varscan2
- DOT1L | c.4535C>G p.S1512C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV101288744; called by muse, mutect2, varscan2
- DPH3 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.449); catalogued as COSV53265080; called by muse, mutect2
- DSCAM | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.909); catalogued as rs555161905, COSV68631131; called by muse, mutect2, varscan2
- DYNC1LI1 | c.1543A>G p.T515A | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV56127078; called by muse, mutect2, varscan2
- ECI2 | c.601G>A p.D201N (on ENST00000380118 / NM_206836.3; = p.D171N on NM_006117.2) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60985579; called by muse, mutect2, varscan2
- EFCAB13 | c.2202G>C p.L734F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58945300; called by muse, mutect2, varscan2
- EFL1 | c.662C>G p.S221C | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV51603683; called by muse, mutect2
- ENPP1 | c.1397A>G p.Y466C | Missense Mutation (SNP) | VAF 76/89 reads (85%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV62931018; called by muse, mutect2, varscan2
- ENTHD1 | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV57318248; called by muse, mutect2, varscan2
- EPAS1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs776459473, COSV55384997; called by muse, mutect2, varscan2
- EPS15 | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | catalogued as COSV100869582; called by muse, mutect2, varscan2
- EPX | c.462_464del p.N154del | In Frame Del (DEL) | VAF 5/50 reads (10%) | catalogued as rs750121261; called by pindel, varscan2
- ERBB3 | c.751G>C p.D251H | Missense Mutation (SNP) | VAF 91/105 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV57248790, COSV57261726; called by muse, mutect2, varscan2
- ERBB3 | c.1256G>C p.G419A | Missense Mutation (SNP) | VAF 36/39 reads (92%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as COSV57248809, COSV57255244; called by muse, mutect2, varscan2
- F12 | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99499844; called by muse, mutect2
- F2RL2 | c.471C>A p.N157K | Missense Mutation (SNP) | VAF 60/78 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56970109; called by muse, mutect2, varscan2
- FADD | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV57229003; called by muse, mutect2, varscan2
- FAHD2B | c.194C>A p.T65K | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.293); catalogued as COSV55630210, COSV55632377; called by muse, mutect2, varscan2
- FAM124A | c.487C>T p.R163W (on ENST00000322475 / NM_001242312.2; = p.R199W on NM_145019.4) | Missense Mutation (SNP) | VAF 25/25 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758162138, COSV54474974; called by muse, mutect2, varscan2
- FAM160B1 | c.2000T>C p.F667S | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs1415099795, COSV65087527; called by muse, mutect2, varscan2
- FAM216A | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 86/103 reads (83%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs749702912, COSV66600098; called by muse, mutect2, varscan2
- FAM234B | c.1369-1G>C p.X457_splice | Splice Site (SNP) | VAF 13/142 reads (9%) | catalogued as COSV52193500; called by muse, mutect2
- FAM3C | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as rs948973252, COSV63435108; called by muse, mutect2, varscan2
- FAM71A | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54234987; called by muse, mutect2
- FAM83B | c.2317C>T p.Q773* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as COSV100174752; called by muse, mutect2, varscan2
- FANCC | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV56658266; called by muse, mutect2
- FAT1 | c.11368G>C p.V3790L | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV71672877; called by muse, mutect2
- FAT3 | c.7861C>G p.Q2621E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs769546478, COSV53088563, COSV53132894; called by muse, mutect2, varscan2
- FBXO10 | c.2688C>G p.F896L | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV52831767, COSV52831928; called by muse, mutect2, varscan2
- FBXO21 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 68/125 reads (54%) | catalogued as rs746654742, COSV100401769; called by muse, mutect2, varscan2
- FBXO4 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 31/328 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV55851600; called by muse, mutect2
- FCHSD2 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.054); catalogued as COSV60807573; called by muse, mutect2, varscan2
- FLG | c.10198C>A p.H3400N | Missense Mutation (SNP) | VAF 164/888 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV64238648; called by muse, mutect2, varscan2
- FLOT1 | c.381C>G p.F127L | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs766681940, COSV52543634; called by muse, mutect2, varscan2
- FOXC2 | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV57443895; called by muse, mutect2, varscan2
- FOXN1 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 104/185 reads (56%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.017); catalogued as rs1213715252, COSV56880910; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.779); catalogued as COSV58548532; called by muse, mutect2, varscan2
- FRMPD3 | c.2449G>C p.E817Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52188121; called by muse, mutect2, varscan2
- FUT4 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781460400, COSV62469090; called by muse, mutect2, varscan2
- GDPD4 | c.94A>G p.I32V | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.135); catalogued as rs775056485, COSV60017935; called by muse, mutect2, varscan2
- GNE | c.386T>A p.V129D (on ENST00000396594 / NM_001128227.3; = p.V98D on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV64951445; called by muse, mutect2, varscan2
- GOLGA3 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 145/291 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as COSV52627440; called by muse, mutect2, varscan2
- GPATCH3 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 31/300 reads (10%) | catalogued as COSV100658868; called by muse, mutect2, varscan2
- GPHN | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV59475445; called by muse, mutect2, varscan2
- GPRASP2 | c.2261A>C p.K754T | Missense Mutation (SNP) | VAF 86/102 reads (84%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV59990616; called by muse, mutect2, varscan2
- GTF2I | c.770C>G p.P257R | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60400163; called by muse, mutect2, varscan2
- GTF3C1 | c.6262G>A p.D2088N | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV62239698; called by muse, mutect2, varscan2
- GTF3C2 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 25/490 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV53125480; called by muse, mutect2
- H3-3A | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV64732196, COSV64733230; called by muse, mutect2, varscan2
- HACL1 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.019); catalogued as COSV57728704; called by muse, mutect2, varscan2
- HEATR5A | c.4464G>C p.E1488D | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.283); catalogued as COSV66339190; called by muse, mutect2
- HEXD | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201473179, COSV60063259; called by muse, mutect2, varscan2
- HFM1 | c.3805G>T p.E1269* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV99646388; called by muse, mutect2, varscan2
- HID1 | c.105C>G p.F35L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.174); catalogued as COSV59351206; called by muse, mutect2, varscan2
- HLA-F | c.818G>C p.G273A | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV52574880; called by muse, mutect2, varscan2
- HOXA6 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339380575, COSV56072115; called by muse, mutect2
- HOXA7 | c.86G>C p.C29S | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV54216968; called by muse, mutect2, varscan2
- HSPA1A | c.1821C>G p.I607M | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.091); catalogued as COSV100989460, COSV65148779; called by muse, mutect2, varscan2
- HSPG2 | c.6162G>C p.K2054N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as COSV65969931; called by muse, mutect2, varscan2
- HTR3B | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as rs771968153, COSV52743205; called by muse, mutect2, varscan2
- IBTK | c.825+1G>A p.X275_splice | Splice Site (SNP) | VAF 48/56 reads (86%) | catalogued as COSV60391652; called by muse, mutect2, varscan2
- IL17RD | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56336109; called by muse, mutect2, varscan2
- IL1RAP | c.770A>G p.E257G | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.322); catalogued as COSV50759750; called by muse, mutect2, varscan2
- INPP5B | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as rs746273464, COSV65957817; called by muse, mutect2, varscan2
- INSR | c.1199C>G p.S400C | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57159462, COSV57172218; called by muse, mutect2, varscan2
- INSRR | c.1867G>A p.V623M | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.888); catalogued as COSV63871584; called by muse, mutect2, varscan2
- IQCF2 | c.207G>T p.R69S | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV60761235; called by muse, mutect2
- IQCK | c.732G>C p.Q244H | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57521783; called by muse, mutect2, varscan2
- ITGA5 | c.722T>A p.I241N | Missense Mutation (SNP) | VAF 65/73 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53216256; called by muse, mutect2, varscan2
- ITM2B | c.344T>G p.I115S | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV66034840; called by muse, mutect2, varscan2
- ITM2B | c.651_654del p.F217Lfs*46 | Frame Shift Del (DEL) | VAF 55/137 reads (40%) | catalogued as rs1337623241; called by mutect2, pindel, varscan2
- ITPKA | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV53027015; called by muse, mutect2, varscan2
- JUP | c.837G>C p.K279N | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV60277421; called by muse, mutect2
- KANK1 | c.3100G>C p.E1034Q | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.139); catalogued as rs768201764, COSV63210142; called by muse, mutect2, varscan2
- KAT6B | c.5356G>A p.E1786K | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs906740657, COSV54744157; called by muse, mutect2
- KAT6B | c.5987G>A p.S1996N | Missense Mutation (SNP) | VAF 123/249 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as COSV54744169; called by muse, mutect2, varscan2
- KCNC2 | c.507C>G p.F169L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV54365041, COSV54370311; called by muse, mutect2, varscan2
- KDM5A | c.3415G>A p.E1139K | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV66991087; called by muse, mutect2, varscan2
- KERA | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 88/102 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57130210; called by muse, mutect2, varscan2
- KIAA1210 | c.2084T>C p.M695T | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV68176142; called by muse, mutect2, varscan2
- KIF15 | c.4149G>C p.K1383N | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs771019926, COSV58159217; called by muse, mutect2, varscan2
- KLHL1 | c.2113G>A p.V705I | Missense Mutation (SNP) | VAF 76/88 reads (86%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV64768337; called by muse, mutect2, varscan2
- KRT32 | c.221C>A p.A74D | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as COSV56785951; called by muse, mutect2, varscan2
- LAMB2 | c.4891G>C p.D1631H | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59731754; called by muse, mutect2, varscan2
- LAMB2 | c.1179C>G p.F393L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs1218135127, COSV59731761; called by muse, mutect2, varscan2
- LATS2 | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 68/251 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV66874162; called by muse, mutect2, varscan2
- LMTK2 | c.3622G>A p.E1208K | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs764183801, COSV51992465, COSV52005563; called by muse, mutect2
- LPAR2 | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV68351954; called by muse, mutect2, varscan2
- LRRC7 | c.498T>C p.S166= (on ENST00000651989 / NM_001370785.2; = p.S133= on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 12/53 reads (23%) | catalogued as COSV50425919; called by muse, mutect2, varscan2
- LTF | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV51606516; called by muse, mutect2
- MACF1 | c.17715G>C p.E5905D (on ENST00000372915; = p.E3950D on NM_012090.5) | Missense Mutation (SNP) | VAF 20/154 reads (13%) | catalogued as COSV57111803; called by muse, mutect2, varscan2
- MAP3K12 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV57231869, COSV57235516; called by muse, mutect2, varscan2
- MAP3K12 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57231885; called by muse, mutect2, varscan2
- MARCHF7 | c.1577C>G p.S526* | Nonsense Mutation (SNP) | VAF 8/135 reads (6%) | catalogued as COSV99373941; called by muse, mutect2
- MAST3 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99445868; called by muse, mutect2, varscan2
- MED13 | c.1750C>T p.Q584* | Nonsense Mutation (SNP) | VAF 70/90 reads (78%) | catalogued as COSV101181200; called by muse, mutect2, varscan2
- METTL25 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV50259875; called by muse, mutect2
- MLC1 | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); catalogued as COSV61116426; called by muse, mutect2, varscan2
- MORC1 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV51716373, COSV51722300; called by muse, mutect2, varscan2
- MRPS6 | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62968661; called by muse, mutect2, varscan2
- MSLNL | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.026); catalogued as rs1363397013, COSV50099976; called by muse, mutect2, varscan2
- MTF1 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV65959891; called by muse, mutect2
- MTHFD1L | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 22/97 reads (23%) | catalogued as rs1401208882, COSV66210296; called by muse, mutect2, varscan2
- MTTP | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV55504575; called by muse, varscan2
- MUSK | c.2042G>A p.S681N | Missense Mutation (SNP) | VAF 104/173 reads (60%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1490647040, COSV51880343; called by muse, mutect2, varscan2
- MX2 | c.481A>C p.K161Q | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV58095660; called by muse, mutect2, varscan2
- MYH9 | c.5041G>A p.E1681K | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1458660141, COSV53383422; called by muse, mutect2, varscan2
- MYNN | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62991041; called by muse, mutect2
- MYO15A | c.3756+1G>A p.X1252_splice | Splice Site (SNP) | VAF 60/92 reads (65%) | catalogued as rs748108031, CS013826, CS163603, CS165233, COSV52753648; called by muse, mutect2, varscan2
- MYO3B | c.2966G>A p.R989H | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201311373, COSV58698104; called by muse, mutect2, varscan2
- NAA35 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64484237; called by muse, mutect2, varscan2
- NBPF3 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 101/333 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59057341, COSV59057637; called by muse, mutect2
- NELFB | c.903C>G p.I301M | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV58024419; called by muse, mutect2, varscan2
- NKTR | c.86C>G p.S29* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV99236072; called by muse, mutect2, varscan2
- NME8 | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV52247803; called by muse, mutect2, varscan2
- NOTCH4 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs746506663, COSV66679513, COSV66679657; called by muse, mutect2, varscan2
- NPHP3 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV58128975, COSV58129679; called by muse, mutect2, varscan2
- NRXN3 | c.1240G>C p.D414H (on ENST00000335750 / NM_001330195.2; = p.D41H on NM_004796.6) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59725767; called by muse, mutect2, varscan2
- NTNG2 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs545516472, COSV62365353; called by muse, mutect2, varscan2
- NUCB2 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs199503493; called by muse, mutect2, varscan2
- NUP155 | c.349C>A p.L117I (on ENST00000231498 / NM_153485.3; = p.L58I on NM_004298.4) | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51528136; called by muse, mutect2, varscan2
- OIP5 | c.219G>C p.E73D | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV52970553; called by muse, mutect2, varscan2
- OR10A4 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as COSV65841772; called by muse, mutect2, varscan2
- OR10R2 | c.600C>A p.D200E | Missense Mutation (SNP) | VAF 101/210 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63768606; called by muse, mutect2, varscan2
- OR11H6 | c.476G>A p.C159Y | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as rs765860463, COSV59643881; called by muse, mutect2, varscan2
- OR2W1 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV65851470; called by muse, mutect2, varscan2
- OR52K1 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV56903267; called by muse, mutect2, varscan2
- OR5P2 | c.252G>C p.E84D | Missense Mutation (SNP) | VAF 111/189 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV61490132; called by muse, mutect2, varscan2
- OXSR1 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV61257946; called by muse, mutect2, varscan2
- PAN3 | c.2111G>C p.G704A | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.375); catalogued as COSV56701708; called by muse, mutect2
- PAX3 | c.260T>G p.L87R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD102008, COSV51337373; called by muse, mutect2, varscan2
- PCDHA13 | c.1282del p.R428Gfs*21 | Frame Shift Del (DEL) | VAF 121/233 reads (52%) | catalogued as COSV56485258, COSV56530849; called by mutect2, pindel, varscan2
- PCDHAC1 | c.2242G>C p.E748Q | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as COSV53841173; called by muse, mutect2, varscan2
- PCDHB11 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 108/157 reads (69%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV53376570; called by muse, mutect2, varscan2
- PCDHB3 | c.357C>G p.N119K | Missense Mutation (SNP) | VAF 79/123 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV50565975; called by muse, mutect2, varscan2
- PCDHGA5 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.166); catalogued as rs868142397, COSV53908755; called by muse, mutect2
- PDGFD | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV56371640; called by muse, mutect2, varscan2
- PDHA2 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV54777907; called by muse, mutect2, varscan2
- PEAK1 | c.2832G>C p.E944D | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV56932381; called by muse, mutect2, varscan2
- PGGT1B | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 76/86 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56973093; called by muse, mutect2, varscan2
- PGR | c.1265C>A p.P422Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV54805730; called by muse, mutect2
- PHACTR1 | c.759del p.P254Qfs*59 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | catalogued as rs749326031; called by mutect2, pindel, varscan2
- PIK3CG | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV63246731; called by muse, mutect2, varscan2
- PIK3CG | c.1304G>A p.C435Y | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV63246738; called by muse, mutect2, varscan2
- PKNOX1 | c.426C>G p.F142L | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52334803; called by muse, mutect2, varscan2
- PLAGL2 | c.1385G>C p.G462A | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.111); catalogued as COSV55787783; called by muse, mutect2, varscan2
- PLBD1 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV53692338; called by muse, mutect2
- PLCB2 | c.2884G>C p.E962Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV53031765; called by muse, mutect2, varscan2
- PLCG1 | c.3772G>A p.E1258K (on ENST00000373271 / NM_182811.2; = p.E1259K on NM_002660.3) | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as rs1267782295, COSV54816407; called by muse, mutect2
- PLEC | c.7872G>C p.E2624D (on ENST00000322810 / NM_201380.4; = p.E2514D on NM_000445.5) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.45); catalogued as COSV59614719; called by muse, mutect2, varscan2
- PLEKHH3 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs147643829; called by muse, mutect2, varscan2
- PLXNA4 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs200749903, COSV58112931; called by muse, mutect2, varscan2
- PLXNC1 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.097); catalogued as rs753220527, COSV51570741; called by muse, mutect2, varscan2
- POLR2B | c.2905C>T p.P969S | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58899231; called by muse, mutect2, varscan2
- PPP4R1 | c.1895C>T p.S632F (on ENST00000400556 / NM_001042388.3; = p.S615F on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV99553789; called by muse, mutect2
- PPP4R3B | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99702379; called by muse, mutect2, varscan2
- PPP5C | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs753540087, COSV50139375; called by muse, mutect2, varscan2
- PRKCB | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 73/106 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as COSV57771033; called by muse, mutect2, varscan2
- PRRC2B | c.698G>C p.R233T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.054); catalogued as COSV61935096; called by muse, mutect2, varscan2
- PSME4 | c.5122A>G p.T1708A | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV66363911; called by muse, mutect2, varscan2
- PTCH1 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV59467077; called by muse, varscan2
- PTCH1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV59467099; called by muse, mutect2, varscan2
- PTPN14 | c.1814C>T p.S605L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs771168517, COSV65282273; called by muse, mutect2, varscan2
- QRICH1 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.243); catalogued as COSV62614851; called by muse, mutect2, varscan2
- RAB39A | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as COSV57694580; called by muse, mutect2
- RAD54L | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64335691; called by muse, mutect2, varscan2
- RAI14 | c.2714C>G p.S905C | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54291270; called by muse, mutect2
- RAPGEF3 | c.766G>C p.E256Q (on ENST00000389212; = p.E214Q on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV50199306; called by muse, mutect2, varscan2
- RASSF6 | c.427G>C p.E143Q (on ENST00000342081 / NM_201431.2; = p.E111Q on NM_177532.5) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.71); catalogued as COSV56716965; called by muse, mutect2, varscan2
- RBBP4 | c.1278G>C p.*426Yext*7 | Nonstop Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100995355, COSV65131201; called by muse, mutect2, varscan2
- RBFOX1 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV60950777, COSV60972926; called by muse, mutect2, varscan2
- RBM42 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 127/301 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as rs778969715, COSV52897044; called by muse, mutect2, varscan2
- RERE | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as rs1338323313, COSV61938715; called by muse, mutect2
- RERE | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61938720; called by muse, mutect2, varscan2
- RETREG2 | c.1486G>C p.D496H | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56087180; called by muse, mutect2, varscan2
- RHEX | c.152del p.Q51Rfs*18 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | catalogued as COSV58979694; called by mutect2, pindel, varscan2
- RIOX1 | c.1820G>A p.R607K | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as COSV100408069; called by muse, mutect2, varscan2
- RLBP1 | c.406G>C p.V136L | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV51527508; called by muse, mutect2, varscan2
- RMC1 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.477); catalogued as COSV52570988; called by muse, mutect2, varscan2
- RNF17 | c.4810G>A p.D1604N | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs371675646; called by muse, mutect2, varscan2
- RNGTT | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.115); catalogued as COSV55647670; called by muse, mutect2, varscan2
- RPS6KL1 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 61/78 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747829572, COSV63580816; called by muse, mutect2, varscan2
- RTN4IP1 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as rs1226585429, COSV64805053; called by muse, mutect2, varscan2
- RXRA | c.428C>G p.S143* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100709322, COSV62684490; called by muse, mutect2, varscan2
- RYR1 | c.2044C>T p.R682W | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776252106, COSV62092384; called by muse, mutect2, varscan2
- RYR3 | c.7774del p.D2592Mfs*14 (on ENST00000389232; = p.D2593Mfs*14 on NM_001036.6) | Frame Shift Del (DEL) | VAF 27/65 reads (42%) | catalogued as COSV66802571; called by mutect2, pindel, varscan2
- SACS | c.3529C>G p.L1177V | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs201533419, COSV66536567; called by muse, mutect2, varscan2
- SAMD9 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV66073730; called by muse, mutect2, varscan2
- SCAMP5 | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62643122; called by muse, mutect2
- SCN3A | c.4101G>A p.M1367I | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs780866749, COSV51804831; called by muse, mutect2
- SELP | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.162); catalogued as rs1185171391, COSV55247086, COSV55249625; called by muse, mutect2, varscan2
- SETD7 | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 27/111 reads (24%) | catalogued as COSV56800931, COSV99918600; called by muse, mutect2, varscan2
- SETMAR | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100740892; called by muse, mutect2, varscan2
- SFI1 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775415101, COSV66290115; called by muse, mutect2, varscan2
- SIMC1 | c.1725G>C p.Q575H (on ENST00000443967 / NM_001308196.1; = p.Q160H on NM_198567.5) | Missense Mutation (SNP) | VAF 71/336 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57901148; called by muse, mutect2, varscan2
- SLC10A7 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs201501147, COSV53881887; called by muse, mutect2, varscan2
- SLC12A6 | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV62543078; called by muse, mutect2, varscan2
- SLC17A7 | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 40/80 reads (50%) | catalogued as COSV99676973; called by muse, mutect2, varscan2
- SLC26A9 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 75/106 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV61600992, COSV61601500; called by muse, mutect2, varscan2
- SLC38A10 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55843660; called by muse, mutect2
- SLC44A2 | c.765C>A p.F255L | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV59835671, COSV59838639; called by muse, mutect2
- SLITRK2 | c.1375A>T p.I459F | Missense Mutation (SNP) | VAF 111/132 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59423861; called by muse, mutect2, varscan2
- SMPDL3B | c.1023C>A p.F341L | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV65854816; called by muse, mutect2
- SNAPC4 | c.3431C>T p.P1144L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs780772303, COSV53731555; called by muse, mutect2, varscan2
- SNTN | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs776027778, COSV59538649; called by muse, mutect2, varscan2
- SP100 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV50975558; called by muse, mutect2, varscan2
- SPINT1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100688861, COSV59801391; called by muse, mutect2, varscan2
- SPINT1 | c.1543G>T p.E515* (on ENST00000344051 / NM_181642.3; = p.E499* on NM_003710.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/387 reads (6%) | catalogued as COSV100689158; called by muse, mutect2
- SPRED3 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV58312163; called by muse, mutect2
- SRGAP3 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs768114904, COSV64531479; called by muse, mutect2, varscan2
- SRSF11 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV63936757; called by muse, mutect2
- SSH2 | c.2371G>C p.E791Q | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV52168328, COSV52174439; called by muse, mutect2, varscan2
- STAC | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56207226, COSV56208140; called by muse, mutect2, varscan2
- STOML1 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as COSV57551164; called by muse, varscan2
- STRIP2 | c.2389G>A p.V797I | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs760420426, COSV50803582, COSV99974070; called by muse, mutect2, varscan2
- STT3A | c.1972C>G p.P658A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV101205244; called by muse, mutect2
- STXBP1 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV64812445; called by muse, mutect2, varscan2
- SVEP1 | c.5756G>T p.S1919I | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV99929448; called by muse, mutect2, varscan2
- SYT4 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV54899091, COSV54904328; called by muse, mutect2, varscan2
- TCF25 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1013912868, COSV99643206; called by muse, mutect2
- TECPR1 | c.3095C>T p.P1032L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1057260553, COSV65782845; called by muse, mutect2, varscan2
- TENM2 | c.4238G>A p.R1413H (on ENST00000518659 / NM_001122679.2; = p.R1174H on NM_001080428.3) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); catalogued as rs78965008, COSV69125093; called by muse, mutect2, varscan2
- TG | c.4981C>T p.R1661C | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as rs901793224, COSV55069428; called by muse, mutect2
- THADA | c.4609C>T p.R1537W | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs1380618914, COSV57678789; called by muse, mutect2, varscan2
- TICRR | c.3372C>G p.I1124M | Missense Mutation (SNP) | VAF 19/394 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.103); catalogued as rs1567052603, COSV51539174; called by muse, mutect2
- TICRR | c.5480C>G p.S1827C | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV51539190; called by muse, mutect2
- TM6SF2 | c.309C>A p.Y103* | Nonsense Mutation (SNP) | VAF 26/88 reads (30%) | catalogued as rs764373234, COSV101231623, COSV101231635; called by muse, mutect2, varscan2
- TMEM131 | c.854C>G p.S285C | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51771963; called by muse, mutect2, varscan2
- TMEM131L | c.2038C>G p.L680V | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53642097; called by muse, mutect2, varscan2
- TMEM243 | c.160C>G p.Q54E | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.028); catalogued as COSV57538172; called by muse, mutect2, varscan2
- TNMD | c.424-1G>C p.X142_splice | Splice Site (SNP) | VAF 33/63 reads (52%) | catalogued as COSV65976952; called by muse, mutect2, varscan2
- TNRC6B | c.1676G>A p.G559E | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57291277; called by muse, varscan2
- TNRC6B | c.1724G>C p.G575A | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57291290; called by muse, varscan2
- TNRC6B | c.2715G>C p.K905N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV57291300; called by muse, mutect2, varscan2
- TOM1L2 | c.475C>G p.L159V (on ENST00000379504 / NM_001350333.2; = p.L109V on NM_001033551.3) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV58884822; called by muse, mutect2, varscan2
- TOR1AIP1 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); catalogued as COSV54868788, COSV54869168, COSV99621581; called by muse, mutect2
- TRIM37 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as COSV51882353; called by muse, mutect2, varscan2
- TRIM69 | c.400T>C p.C134R | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57803208; called by muse, mutect2, varscan2
- TSHZ1 | c.145G>A p.E49K (on ENST00000580243 / NM_001308210.2; = p.E4K on NM_005786.6) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.193); catalogued as COSV100433841; called by muse, mutect2
- TTC14 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.145); catalogued as COSV56010016; called by muse, mutect2, varscan2
- TTN | c.100523C>G p.S33508C (on ENST00000591111; = p.S26084C on NM_003319.4) | Missense Mutation (SNP) | VAF 31/235 reads (13%) | PolyPhen probably damaging (0.935); catalogued as COSV59942942; called by muse, mutect2, varscan2
- TUBB1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 72/131 reads (55%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as rs1394068606, COSV53886193; called by muse, mutect2, varscan2
- TUT4 | c.1364T>A p.V455D | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57111335; called by muse, mutect2, varscan2
- UACA | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100537618; called by muse, mutect2, varscan2
- UBE3C | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs759130893, COSV61952104; called by muse, mutect2, varscan2
- UBR4 | c.13963G>T p.D4655Y | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64384738; called by muse, mutect2, varscan2
- UBR4 | c.5083G>T p.A1695S | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64384752; called by muse, mutect2, varscan2
- UFSP2 | c.865C>G p.H289D | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52990940; called by muse, mutect2
- UROS | c.355T>C p.C119R | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV64223414; called by muse, mutect2, varscan2
- USP34 | c.5275G>C p.D1759H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV101277175, COSV68399461; called by muse, mutect2, varscan2
- USP34 | c.3877G>C p.D1293H | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV68399464; called by muse, mutect2, varscan2
- USP36 | c.1664G>T p.G555V | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT deleterious (0.05); PolyPhen benign (0.44); catalogued as COSV61750801; called by muse, mutect2, varscan2
- USP43 | c.2681C>T p.S894L | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs756895822, COSV53300717; called by muse, mutect2, varscan2
- USP5 | c.1934C>G p.P645R | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV57536019, COSV57536491, COSV99978802; called by muse, mutect2, varscan2
- USP53 | c.1469C>G p.S490C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV56793148, COSV56797241; called by muse, mutect2, varscan2
- USP7 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as COSV61213476; called by muse, mutect2, varscan2
- UTP18 | c.1591C>G p.P531A | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV56582645; called by muse, varscan2
- UTP25 | c.1269C>A p.D423E | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71965810, COSV71966146; called by muse, mutect2
- VCL | c.2060G>T p.G687V | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV53007851; called by muse, mutect2
- VPS18 | c.2373C>G p.F791L | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV55029339; called by muse, mutect2
- WAS | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1557007058, COSV100939440, COSV64996604; called by muse, mutect2, varscan2
- WDR64 | c.2752G>T p.D918Y | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs375495995, COSV63793625; called by muse, mutect2, varscan2
- WWC3 | c.2599-2A>T p.X867_splice | Splice Site (SNP) | VAF 155/173 reads (90%) | catalogued as COSV66502081; called by muse, mutect2, varscan2
- XPO1 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV68945079; called by muse, mutect2
- XPO5 | c.10G>C p.D4H | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.401); catalogued as COSV54828379; called by muse, mutect2, varscan2
- YEATS2 | c.2435G>T p.G812V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV59361540, COSV59363195; called by muse, mutect2, varscan2
- YLPM1 | c.3106C>A p.L1036I | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.829); catalogued as COSV53108357; called by muse, mutect2, varscan2
- ZBED1 | c.1632C>G p.I544M | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.503); catalogued as COSV58131509; called by muse, mutect2, varscan2
- ZBTB38 | c.3231G>C p.L1077F | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as COSV58540745; called by muse, mutect2
- ZC3H4 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 22/555 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV53410767, COSV53417444; called by muse, mutect2
- ZFHX4 | c.2340G>C p.R780S | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV51496827, COSV99265544; called by muse, mutect2
- ZNF107 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.465); catalogued as COSV61327403; called by muse, mutect2, varscan2
- ZNF19 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV99867575; called by muse, mutect2, varscan2
- ZNF223 | c.197G>C p.W66S | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV71571810; called by muse, mutect2, varscan2
- ZNF329 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV63771927; called by muse, mutect2, varscan2
- ZNF398 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 54/64 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs145157368, COSV60064796; called by muse, mutect2, varscan2
- ZNF510 | c.448A>G p.T150A | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV56296629; called by muse, mutect2, varscan2
- ZNF620 | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.132); catalogued as COSV58820164; called by muse, mutect2, varscan2
- ZNF644 | c.3517G>C p.E1173Q | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.974); catalogued as COSV61346492; called by muse, varscan2
- ZNF644 | c.3454G>A p.E1152K | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV61346501; called by muse, varscan2
- ZNFX1 | c.4988G>T p.R1663L | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV65595355; called by muse, mutect2, varscan2
- ZSCAN22 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100308435, COSV61639044; called by muse, mutect2
- CLUH | c.216G>C p.E72D (on ENST00000435359; = p.E110D on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.275); called by muse, mutect2
- CRYBG2 | c.4769del p.G1590Dfs*42 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | called by mutect2, varscan2
- DLAT | c.1526_1528del p.V509del | In Frame Del (DEL) | VAF 9/27 reads (33%) | called by pindel, varscan2
- FAT4 | c.4131del p.K1377Nfs*12 | Frame Shift Del (DEL) | VAF 32/192 reads (17%) | called by mutect2, pindel, varscan2
- HNRNPH1 | c.1080_1082del p.F360del | In Frame Del (DEL) | VAF 14/96 reads (15%) | called by pindel, varscan2
- IP6K1 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2
- KHDRBS2 | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- NECTIN1 | c.1495_1497delinsAA p.E499Kfs*99 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by muse*, pindel
- PRRC2B | c.3485del p.L1162Rfs*8 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- RANBP3 | c.1066G>T p.E356* (on ENST00000340578 / NM_007322.3; = p.E351* on NM_003624.3) | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- SMYD2 | c.1188del p.E396Dfs*10 | Frame Shift Del (DEL) | VAF 16/146 reads (11%) | called by mutect2, pindel, varscan2
- ACOX1 | c.960G>A p.Q320= | Silent (SNP) | VAF 7/144 reads (5%) | catalogued as COSV53131894; called by muse, mutect2
- ADAM19 | c.1764C>T p.N588= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as rs370590283; called by muse, mutect2, varscan2
- AMPH | c.2064G>A p.E688= | Silent (SNP) | VAF 45/195 reads (23%) | catalogued as COSV57736679; called by muse, mutect2, varscan2
- ANO3 | c.132C>T p.Y44= | Silent (SNP) | VAF 84/236 reads (36%) | catalogued as rs775066580, COSV56784591; called by muse, mutect2, varscan2
- APBA1 | c.2100G>C p.L700= | Silent (SNP) | VAF 31/193 reads (16%) | catalogued as COSV55223589; called by muse, mutect2, varscan2
- ARC | c.588G>A p.P196= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV63078203; called by muse, mutect2, varscan2
- ATP10A | c.4164G>C p.L1388= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV63515016; called by muse, mutect2
- BCAS3 | c.2769C>T p.F923= (on ENST00000390652 / NM_001353144.2; = p.F908= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs1216457957, COSV66771196; called by muse, mutect2, varscan2
- BIRC6 | c.9786C>T p.L3262= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs761498168, COSV70196959; called by muse, mutect2, varscan2
- C18orf25 | c.504C>T p.V168= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as rs767780796, COSV56365638; called by muse, mutect2, varscan2
- CA4 | c.22C>T p.L8= | Silent (SNP) | VAF 29/41 reads (71%) | catalogued as COSV56281131; called by muse, mutect2, varscan2
- CALN1 | c.645G>C p.R215= (on ENST00000329008 / NM_001017440.3; = p.R257= on NM_031468.4) | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV61123899; called by muse, mutect2
- CATSPERE | c.1245C>T p.V415= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV63676783; called by muse, mutect2
- CCND3 | c.39C>A p.P13= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as COSV100882232; called by muse, mutect2, varscan2
- CD5 | c.1479G>A p.Q493= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1193970485, COSV57108269; called by muse, mutect2, varscan2
- CERS5 | c.912C>T p.I304= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as rs752285189, COSV58188660; called by muse, mutect2, varscan2
- CHPT1 | c.390C>G p.L130= | Silent (SNP) | VAF 33/195 reads (17%) | catalogued as COSV57532894; called by muse, mutect2, varscan2
- CIBAR2 | c.177C>T p.S59= | Silent (SNP) | VAF 52/79 reads (66%) | catalogued as rs771669601, COSV73320556; called by muse, mutect2, varscan2
- CLSTN1 | c.2385A>T p.S795= (on ENST00000377298 / NM_001009566.3; = p.S785= on NM_014944.4) | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV63647081; called by muse, mutect2, varscan2
- CNTN4 | c.1953C>T p.L651= | Silent (SNP) | VAF 35/240 reads (15%) | catalogued as COSV61869789; called by muse, mutect2, varscan2
- COG3 | c.2250G>A p.A750= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs774362382, COSV63071752; called by mutect2, varscan2
- COL15A1 | c.3078G>A p.L1026= | Silent (SNP) | VAF 16/290 reads (6%) | catalogued as rs1405552827, COSV66642315; called by muse, mutect2
- CSPP1 | c.1812G>A p.T604= (on ENST00000676605; = p.T563= on NM_024790.6) | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs538426847, COSV51581607; called by muse, mutect2, varscan2
- DEF8 | c.897C>T p.Y299= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV51918376; called by muse, mutect2
- DENND4B | c.3343C>T p.L1115= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV63407827; called by muse, mutect2, varscan2
- DHPS | c.906C>T p.Y302= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs542424645, COSV99269510; called by muse, mutect2
- DISP2 | c.3166C>T p.L1056= | Silent (SNP) | VAF 23/193 reads (12%) | catalogued as rs760017067, COSV51117650; called by muse, mutect2, varscan2
- DOCK2 | c.3654G>A p.E1218= | Silent (SNP) | VAF 32/41 reads (78%) | catalogued as COSV56948085; called by muse, mutect2, varscan2
- DUS2 | c.180C>G p.L60= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV62708096; called by muse, mutect2, varscan2
- DUSP7 | c.855C>T p.F285= | Silent (SNP) | VAF 57/258 reads (22%) | catalogued as rs1444614926, COSV56588781; called by muse, mutect2, varscan2
- EDEM2 | c.1011C>G p.L337= | Silent (SNP) | VAF 9/155 reads (6%) | catalogued as COSV65712690; called by muse, mutect2
- ENPP2 | c.768A>C p.G256= | Silent (SNP) | VAF 46/144 reads (32%) | catalogued as COSV50011246; called by muse, mutect2, varscan2
- EPHA3 | c.1668C>G p.L556= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV60698208, COSV60726682; called by muse, mutect2, varscan2
- ERBB3 | c.2526C>G p.L842= | Silent (SNP) | VAF 9/191 reads (5%) | catalogued as COSV57248822; called by muse, mutect2
- EXT1 | c.816G>T p.L272= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV65476538; called by muse, mutect2, varscan2
- FASTKD1 | c.1162C>T p.L388= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV71624148; called by muse, mutect2, varscan2
- FAT2 | c.3579C>A p.L1193= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV55815628; called by muse, mutect2, varscan2
- FBXL2 | c.240G>A p.L80= | Silent (SNP) | VAF 46/347 reads (13%) | catalogued as COSV52137450; called by muse, mutect2, varscan2
- FREM2 | c.5742G>A p.L1914= | Silent (SNP) | VAF 134/151 reads (89%) | catalogued as COSV54831779; called by muse, mutect2, varscan2
- FRMPD3 | c.4248G>A p.L1416= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV52188145; called by muse, mutect2
- FUT4 | c.1470G>C p.R490= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV62469099; called by muse, mutect2, varscan2
- FZD1 | c.714G>T p.P238= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV55309400; called by muse, mutect2, varscan2
- GFOD2 | c.825G>C p.T275= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV52057342; called by muse, mutect2, varscan2
- GGA3 | c.633G>A p.V211= (on ENST00000537686 / NM_138619.4; = p.V178= on NM_014001.5) | Silent (SNP) | VAF 29/244 reads (12%) | catalogued as COSV55455788; called by muse, mutect2, varscan2
- GPR89B | c.981G>C p.V327= | Silent (SNP) | VAF 21/211 reads (10%) | called by muse, mutect2, varscan2
- GPRIN2 | c.795G>A p.V265= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as rs781851009, COSV65400640; called by muse, mutect2, varscan2
- HGSNAT | c.1629C>T p.V543= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs1310490354, COSV52816564; called by muse, mutect2, varscan2
- HPS5 | c.3360C>T p.C1120= (on ENST00000349215 / NM_181507.2; = p.C1006= on NM_007216.4) | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs779428154, COSV61687257; called by muse, mutect2, varscan2
- HSCB | c.693G>A p.K231= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99319747; called by muse, mutect2
- IPO5 | c.2433A>G p.R811= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV55152909; called by muse, mutect2, varscan2
- KBTBD2 | c.1032C>T p.F344= | Silent (SNP) | VAF 39/162 reads (24%) | catalogued as COSV58362997; called by muse, mutect2, varscan2
- KDM4B | c.2520C>T p.I840= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV50211405; called by muse, mutect2, varscan2
- KIRREL3 | c.486G>A p.A162= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs753719353, COSV73104930; called by muse, mutect2, varscan2
- KMT2A | c.8403C>A p.L2801= | Silent (SNP) | VAF 36/203 reads (18%) | catalogued as COSV63281993, COSV63283460; called by muse, mutect2, varscan2
- KRT9 | c.801G>T p.L267= | Silent (SNP) | VAF 25/222 reads (11%) | catalogued as COSV55851969; called by muse, mutect2, varscan2
- KRTAP8-1 | c.156C>T p.F52= | Silent (SNP) | VAF 73/194 reads (38%) | catalogued as rs201803377, COSV61597805; called by muse, mutect2, varscan2
- LAMB2 | c.537C>G p.S179= | Silent (SNP) | VAF 51/220 reads (23%) | catalogued as rs747190887, COSV59731769; called by muse, mutect2, varscan2
- LILRA2 | c.141C>T p.L47= | Silent (SNP) | VAF 82/206 reads (40%) | catalogued as COSV52189612; called by muse, varscan2
- LRP5 | c.3144C>T p.I1048= | Silent (SNP) | VAF 82/166 reads (49%) | catalogued as rs1306129759, COSV53712952; called by muse, mutect2, varscan2
- LRRC4C | c.1218C>T p.L406= | Silent (SNP) | VAF 77/227 reads (34%) | catalogued as rs772020632, COSV53420720, COSV53425689; called by muse, mutect2, varscan2
- LRRC58 | c.417C>T p.L139= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs756325581, COSV55229748; called by muse, mutect2, varscan2
- LRRTM1 | c.192G>T p.L64= | Silent (SNP) | VAF 49/68 reads (72%) | catalogued as COSV54439405; called by muse, mutect2, varscan2
- MTPN | c.252G>A p.V84= | Silent (SNP) | VAF 28/285 reads (10%) | catalogued as COSV67599400; called by muse, mutect2
- MYL4 | c.219C>T p.I73= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs752046263, COSV61698112; called by muse, mutect2, varscan2
- MYO1E | c.1377C>T p.I459= | Silent (SNP) | VAF 71/81 reads (88%) | catalogued as COSV55682410, COSV55683846, COSV99894049; called by muse, mutect2, varscan2
- NLRC4 | c.1959C>T p.F653= | Silent (SNP) | VAF 31/235 reads (13%) | catalogued as COSV61591811; called by muse, mutect2, varscan2
- NLRP2 | c.1320C>T p.G440= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs761761609, COSV99672477; called by muse, mutect2, varscan2
- NR6A1 | c.1380G>A p.E460= (on ENST00000487099 / NM_033334.4; = p.E455= on NM_001489.5) | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV100748633; called by muse, mutect2, varscan2
- NUAK1 | c.1488G>C p.V496= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as rs772269401, COSV54601461; called by muse, mutect2, varscan2
- OR1D5 | c.825G>A p.V275= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs773097613, COSV101643437; called by mutect2, varscan2
- OR5AN1 | c.753C>G p.L251= | Silent (SNP) | VAF 19/139 reads (14%) | catalogued as COSV58321816; called by muse, mutect2, varscan2
- OVOL1 | c.114C>T p.F38= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV60119584; called by muse, mutect2, varscan2
- PAX3 | c.261G>T p.L87= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV51337314; called by mutect2, varscan2
- PCDH15 | c.3540C>A p.A1180= | Silent (SNP) | VAF 41/75 reads (55%) | catalogued as COSV57276411; called by muse, mutect2, varscan2
- PCDHA9 | c.504C>T p.L168= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs782437176, COSV100969876; called by muse, mutect2, varscan2
- PCDHB15 | c.1857G>A p.A619= | Silent (SNP) | VAF 23/145 reads (16%) | catalogued as rs1217877580, COSV50865650; called by muse, mutect2, varscan2
- PCDHB2 | c.2157C>T p.S719= | Silent (SNP) | VAF 142/240 reads (59%) | catalogued as COSV99165895; called by muse, mutect2, varscan2
- PGM2 | c.1764G>A p.L588= | Silent (SNP) | VAF 44/206 reads (21%) | catalogued as COSV67938544; called by muse, mutect2, varscan2
- PIPOX | c.894G>C p.L298= | Silent (SNP) | VAF 17/324 reads (5%) | catalogued as COSV60141256; called by muse, mutect2
- PLA2G4C | c.1575G>T p.V525= | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as COSV62784466; called by muse, mutect2, varscan2
- PLEKHG5 | c.1728G>A p.A576= (on ENST00000400915 / NM_001042663.3; = p.A539= on NM_020631.6) | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs545959722, COSV61067959; called by muse, mutect2, varscan2
- POMK | c.231G>A p.L77= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV58856743; called by muse, mutect2, varscan2
- PSG3 | c.903G>C p.T301= | Silent (SNP) | VAF 44/428 reads (10%) | catalogued as COSV59503120, COSV59507174; called by muse, mutect2, varscan2
- QTRT1 | c.1179C>T p.D393= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as rs375875231; called by muse, mutect2, varscan2
- RANBP17 | c.2697T>C p.H899= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV66646182; called by muse, mutect2, varscan2
- RFPL2 | c.879G>A p.P293= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs559935317, COSV99964429; called by muse, mutect2, varscan2
- RIMS2 | c.1269T>C p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 58/120 reads (48%) | catalogued as rs778061023, COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- RNF123 | c.99G>A p.K33= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV59685283; called by muse, mutect2, varscan2
- RNF123 | c.1578C>T p.I526= | Silent (SNP) | VAF 17/509 reads (3%) | catalogued as COSV59685290; called by muse, mutect2
- RRN3 | c.1041G>C p.L347= | Silent (SNP) | VAF 9/119 reads (8%) | catalogued as rs146935511; called by muse, mutect2
- RTL4 | c.895C>A p.R299= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as CM134623, COSV61205800, COSV61206933; called by muse, varscan2
- SALL3 | c.1107C>T p.S369= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs773316503, COSV73305869, COSV73305936; called by muse, mutect2, varscan2
- SCLY | c.951G>A p.A317= (on ENST00000651534; = p.A309= on NM_016510.7) | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs938656338, COSV54540587; called by muse, mutect2, varscan2
- SEMA6C | c.714C>T p.F238= | Silent (SNP) | VAF 22/221 reads (10%) | catalogued as rs371970591, COSV59008601; called by muse, mutect2, varscan2
- SERPINE2 | c.792G>T p.P264= | Silent (SNP) | VAF 36/46 reads (78%) | catalogued as COSV51456402, COSV51458928; called by muse, varscan2
- SIPA1L1 | c.1812A>G p.E604= | Silent (SNP) | VAF 63/79 reads (80%) | catalogued as COSV62169103; called by muse, mutect2, varscan2
- SLC15A4 | c.1176G>A p.L392= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as COSV57160783, COSV57163325; called by muse, mutect2, varscan2
- SLC44A1 | c.981C>G p.V327= | Silent (SNP) | VAF 38/220 reads (17%) | catalogued as rs1216449744, COSV58262886; called by muse, mutect2, varscan2
- SLC9A8 | c.1254C>T p.F418= | Silent (SNP) | VAF 18/210 reads (9%) | catalogued as COSV64287659; called by muse, mutect2
- SMARCAL1 | c.405A>G p.K135= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV61920339; called by muse, mutect2
- SMC5 | c.960G>A p.L320= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV63192080; called by muse, mutect2, varscan2
- SPINT1 | c.1356G>A p.L452= (on ENST00000344051 / NM_181642.3; = p.L436= on NM_003710.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as COSV59801396; called by muse, mutect2, varscan2
- ST8SIA6 | c.957C>T p.Y319= | Silent (SNP) | VAF 153/230 reads (67%) | catalogued as COSV101112057, COSV66466843; called by muse, mutect2, varscan2
- SYN1 | c.693G>A p.Q231= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV55980319; called by muse, mutect2, varscan2
- TECPR1 | c.1017C>T p.N339= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs769134413, COSV101130616; called by muse, varscan2
- TENM3 | c.1977T>A p.L659= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV69302210; called by muse, mutect2, varscan2
- THBS1 | c.1833G>A p.T611= | Silent (SNP) | VAF 130/210 reads (62%) | catalogued as rs776040943, COSV52950757; called by muse, mutect2, varscan2
- TNIK | c.1500A>G p.L500= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV52676918, COSV52689731; called by muse, mutect2, varscan2
- TNRC18 | c.6822C>G p.L2274= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV60306706; called by muse, mutect2
- TNS3 | c.498C>G p.L166= | Silent (SNP) | VAF 29/44 reads (66%) | catalogued as COSV60788481; called by muse, mutect2, varscan2
- TNS4 | c.2049G>A p.E683= | Silent (SNP) | VAF 26/199 reads (13%) | catalogued as COSV54183940; called by muse, mutect2, varscan2
- TRIM42 | c.978C>T p.L326= | Silent (SNP) | VAF 36/171 reads (21%) | catalogued as COSV53880920; called by muse, mutect2, varscan2
- TRIM49 | c.354T>G p.S118= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs971785858, COSV100316169; called by muse, mutect2, varscan2
- TRMT2A | c.999C>T p.H333= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1256963226, COSV52813306, COSV99350148; called by muse, mutect2
- TRPV1 | c.1794G>A p.L598= | Silent (SNP) | VAF 27/31 reads (87%) | catalogued as COSV51516482; called by muse, mutect2, varscan2
- UBR2 | c.3918G>A p.T1306= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs760553928, COSV65749307; called by muse, mutect2, varscan2
- UMODL1 | c.849A>G p.A283= | Silent (SNP) | VAF 49/195 reads (25%) | catalogued as COSV68555195; called by muse, mutect2, varscan2
- USP36 | c.882G>A p.L294= | Silent (SNP) | VAF 31/304 reads (10%) | catalogued as COSV61750810; called by muse, mutect2, varscan2
- UTP18 | c.1374C>T p.L458= | Silent (SNP) | VAF 32/37 reads (86%) | catalogued as COSV56582637; called by muse, mutect2, varscan2
- VCAM1 | c.720C>T p.G240= | Silent (SNP) | VAF 49/79 reads (62%) | catalogued as COSV54118322; called by muse, mutect2, varscan2
- VPS18 | c.1545C>G p.L515= | Silent (SNP) | VAF 16/312 reads (5%) | catalogued as COSV55029331; called by muse, mutect2
- ZIC5 | c.1488C>G p.P496= | Silent (SNP) | VAF 17/216 reads (8%) | catalogued as rs1328353865, COSV57436717; called by muse, mutect2
- ZKSCAN2 | c.1953A>T p.G651= | Silent (SNP) | VAF 38/221 reads (17%) | catalogued as COSV60156012; called by muse, mutect2, varscan2
- ZNF320 | c.1296G>A p.R432= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as rs1387954453, COSV67087750; called by muse, mutect2, varscan2
- ZNF462 | c.3639G>A p.Q1213= | Silent (SNP) | VAF 83/628 reads (13%) | catalogued as COSV52933197; called by muse, mutect2, varscan2
- ZNF831 | c.3525C>G p.P1175= | Silent (SNP) | VAF 119/204 reads (58%) | catalogued as COSV64038436; called by muse, mutect2, varscan2
- C3orf20 | c.-1C>G | 5'UTR (SNP) | VAF 20/190 reads (11%) | catalogued as COSV53783391; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415344 T>C | 5'Flank (SNP) | VAF 68/169 reads (40%) | catalogued as COSV52567093, COSV52567749, COSV52568626; called by muse, mutect2, varscan2
- EML2 | c.21-147G>C | Intron (SNP) | VAF 18/89 reads (20%) | catalogued as rs779437713, COSV99840240; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055653 G>A | 3'Flank (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- GSK3B | c.910-3016C>T | Intron (SNP) | VAF 26/284 reads (9%) | catalogued as COSV51772379; called by muse, mutect2
- PLEKHA8P1 | n.712G>C | RNA (SNP) | VAF 132/237 reads (56%) | called by muse, mutect2, varscan2
- RPL21 | c.130-108C>G | Intron (SNP) | VAF 12/74 reads (16%) | catalogued as COSV99699267; called by muse, mutect2, varscan2
- SCGB1D1 | c.*1G>C | 3'UTR (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100086773, COSV100086810; called by muse, mutect2
- SMTN | c.1633-1690G>A | Intron (SNP) | VAF 7/14 reads (50%) | catalogued as rs1254468470, COSV100294720; called by muse, mutect2, varscan2
- SSPOP | n.5717G>C | RNA (SNP) | VAF 31/35 reads (89%) | catalogued as COSV100022763; called by muse, mutect2, varscan2
- SV2C | c.581-20797A>G | Intron (SNP) | VAF 70/78 reads (90%) | called by muse, mutect2, varscan2
